Somatic mutation profile of tumor specimen C3L-01962-01 (aliquot CPT0389650006) from CPTAC case C3L-01962, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.4 years (24,969 days).
Specimen C3L-01962-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e8b44f2-517b-4e0e-8fc5-0118c4b3a8f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01962-31 (Blood Derived Normal), aliquot CPT0389710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dcd4d7f-5c4d-41ce-bd4e-938f9121c80c

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Intron 7, 3'UTR 3, 5'UTR 2, Splice Site 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOD1L2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated, low confidence (0.85); PolyPhen possibly damaging (0.601); catalogued as rs1395258895; called by muse, mutect2, varscan2
- CDC42BPG | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV61348681; called by muse, mutect2, varscan2
- CUBN | c.5131G>A p.A1711T | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as rs768182223, COSV64725333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM221A | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61387680; called by muse, mutect2, varscan2
- H1-7 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs764466546; called by mutect2, varscan2
- ITGB5 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.533); catalogued as rs201900103; called by muse, mutect2
- NID2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs151032833; called by muse, mutect2, varscan2
- PEG3 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs376020685; called by muse, mutect2, varscan2
- PLAGL2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 141/463 reads (30%) | catalogued as COSV55789304; called by muse, mutect2, varscan2
- SPINK5 | c.2423C>A p.T808N | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as CM074575; called by muse, mutect2
- TSGA13 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1554462377; called by muse, mutect2, varscan2
- UGT2A2 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs761322290; called by muse, mutect2, varscan2
- ASPHD2 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- AXIN2 | c.2222G>T p.S741I | Missense Mutation (SNP) | VAF 328/581 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCL7C | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 178/263 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- CAPRIN2 | c.2911C>T p.L971F | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBWD5 | c.1081+2dup p.X361_splice (on ENST00000382405 / NM_001330668.1; = p.X313_splice on NM_001024916.3) | Splice Site (INS) | VAF 85/525 reads (16%) | called by mutect2, pindel, varscan2
- CDHR2 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CENATAC | c.579C>T p.S193= | Splice Region (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- CPA1 | c.1246A>T p.N416Y | Missense Mutation (SNP) | VAF 35/543 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- EGLN1 | c.607A>G p.N203D | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FCHO2 | c.259C>A p.H87N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LRRC34 | c.729C>G p.N243K | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MEGF8 | c.3793G>A p.G1265S (on ENST00000251268 / NM_001271938.2; = p.G1198S on NM_001410.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MRM1 | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.232); called by muse, mutect2
- PARP11 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PEG3 | c.1535A>T p.E512V | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLAGL2 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RABEP1 | c.2066T>G p.I689S | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- REC8 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNTB1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SVEP1 | c.5404G>T p.G1802C | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TBRG1 | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRAF7 | c.893dup p.H299Pfs*40 | Frame Shift Ins (INS) | VAF 346/700 reads (49%) | called by mutect2, pindel, varscan2
- UPK1B | c.732+1G>A p.X244_splice | Splice Site (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- ZNF155 | c.1589T>G p.L530R | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF83 | c.1481T>C p.F494S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATG16L1 | c.702C>T p.V234= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs369995634; called by muse, mutect2, varscan2
- COMMD5 | c.63A>G p.R21= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- FBXW8 | c.1351C>T p.L451= (on ENST00000309909; = p.L489= on NM_012174.1) | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2
- GCN1 | c.5025C>G p.T1675= | Silent (SNP) | VAF 73/163 reads (45%) | called by muse, mutect2, varscan2
- NEB | c.19080A>G p.K6360= | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- SDR9C7 | c.354C>T p.N118= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as rs373685313; called by muse, mutect2, varscan2
- SPNS2 | c.1092C>T p.L364= | Silent (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.1116G>A p.L372= | Silent (SNP) | VAF 37/229 reads (16%) | catalogued as rs1459616729, COSV52110680; called by muse, mutect2, varscan2
- DIP2A | c.3969+75G>A | Intron (SNP) | VAF 16/152 reads (11%) | catalogued as rs1342705980; called by muse, mutect2, varscan2
- DNAH14 | c.749-4195G>A | Intron (SNP) | VAF 23/56 reads (41%) | catalogued as rs772658803; called by muse, mutect2, varscan2
- DNAJC19 | c.*266dup | 3'UTR (INS) | VAF 78/223 reads (35%) | called by mutect2, pindel, varscan2
- FARP1 | c.2274+243T>G | Intron (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2
- GNLY | c.-4C>A | 5'UTR (SNP) | VAF 39/228 reads (17%) | called by muse, mutect2, varscan2
- ITSN1 | c.2728-811G>A | Intron (SNP) | VAF 53/406 reads (13%) | catalogued as rs1055825138, COSV66082729; called by muse, mutect2, varscan2
- MAP3K15 | c.1749-1255del | Intron (DEL) | VAF 22/34 reads (65%) | called by mutect2, pindel, varscan2
- QARS1 | c.266-97G>T | Intron (SNP) | VAF 82/178 reads (46%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*588A>G | 3'UTR (SNP) | VAF 110/256 reads (43%) | called by muse, mutect2, varscan2
- TMCO1 | c.*829G>T | 3'UTR (SNP) | VAF 90/160 reads (56%) | called by muse, mutect2, varscan2
- TRPM4 | c.1873+50G>A | Intron (SNP) | VAF 46/127 reads (36%) | catalogued as rs751543003; called by muse, mutect2, varscan2
- ZNF48 | c.-267T>G | 5'UTR (SNP) | VAF 140/249 reads (56%) | called by muse, mutect2, varscan2
